Somatic mutation profile of tumor specimen 0DYG0I from CCDI case PBCSID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.8 years (3,229 days).
Specimen 0DYG0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa89b6d4-8486-4b8b-b979-c6e0fa633059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYFZ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a11e0a57-ad6f-4230-80d2-e3b97bcdb243

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/1269 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SRPK3 | c.1311C>T p.G437= | Silent (SNP) | VAF 46/392 reads (12%) | catalogued as rs782398607; called by muse, mutect2, varscan2
- AIFM1 | c.249+1095C>T | Intron (SNP) | VAF 18/247 reads (7%) | called by muse, mutect2
- CACNA2D4 | c.3309+14C>T | Intron (SNP) | VAF 35/304 reads (12%) | called by muse, mutect2, varscan2
- TK2 | c.64-4787C>T | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as rs1224594300; called by muse, mutect2, varscan2
